Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2A5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2A5-06A (Metastatic).

DOB/Age/sex
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Melanoma left forearm - previously excised. Now chain of in transit metastasis extending from elbow to axilla in line of basilic vein. Refer:

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar:

MACROSCOPIC DESCRIPTION

(Dr

"MULTIPLE TUMOUR LEFT ARM STAPLE UPPER". The specimen is an orientated skin ellipse measuring 230 x 14 x depth of 15mm. There are seven blue markings on the skin surface and there is a small scar measuring approximately 4mm in length in the middle of the skin ellipse. There is a staple at one pole, allocated as upper, allocated as 12 o'clock. 3 o'clock half inked blue, 9 o'clock half blue.

The third lowest marking has been sampled for melanoma tumour banking.

Sections have been taken from 12 o'clock to 6 o'clock. Three definite subcutaneous nodules have been visualised on slicing.

- A. Slice 25 with a small pale brownish nodule measuring approximately 3mm in diameter.
- B. Slice 26, with a nodule measuring approximately 7mm in diameter ?metastasis ?lymph node.

Photographs taken

MICROSCOPIC REPORT

"MULTIPLE TUMOUR LEFT ARM STAPLE UPPER": Sections of skin show within the subcutaneous fat nodules of tumour composed of epithelioid cells with abundant eosinophilic cytoplasm and enlarged nuclei with prominent nucleoli and occasional intranuclear inclusions. In some of the nodules pigment is seen consistent with melanin.

Immunohistochemistry for S100, HMB45 and Melan A is positive. These appearances are in keeping with deposits of malignant melanoma.

The nodules appear clear of the soft tissue margins with the closest margin being the deep margin which is 2mm clear of the tumour deposits. The overlying epidermis shows no insitu component.

SUMMARY

Multiple tumours left arm - melanoma confirmed.

REPORTED BY Dr
Proxy Verified by

A Unit of

This fax was received by

Page 1 of 1

TCGA t. recurrence		

Source: NCI Genomic Data Commons file 8f6dcb39-02d9-4f56-b6b3-241164fcdad3 (TCGA-EE-A2A5.FE4DB085-F3A6-4AAC-88C2-AD1936EBDA1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).